Gene-level copy-number profile of specimen HCM-CSHL-0438-C18-85A from HCMI case HCM-CSHL-0438-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0438-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file af152a09-761e-4328-9061-02ef4c01da6c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0438-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/cdfa6659-d080-4846-93e8-484183191347

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 58; copy number 1: 9; copy number 2: 923; copy number 3: 312; copy number 4: 28,737; copy number 5: 383; copy number 6: 22,688; copy number 7: 454; copy number 8: 4,264; copy number 9: 25; copy number 11: 1,026.

Homozygous deletions (total copy number 0; autosomes only): 58 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:67,173,511–71,592,025, 58 genes (within-gene range 0–4): ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1, Y_RNA, RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1, LINC01603, AC022790.1, SULF1, SLCO5A1, RN7SKP29, AC091047.1, AC079089.3, AC079089.1, Metazoa_SRP, AC079089.2, RN7SL675P, RNA5SP270, AC090574.1, SDCBPP2, SUMO2P20, PRDM14, RNU1-101P, H2AZP2, NCOA2, BTF3P12, RNY3P14, AC022730.2, AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1, EYA1, TRAPPC2P2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,051 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:111,674,676–112,294,227, 14 genes, copy number 9: PLCXD2, PLCXD2-AS1, PHLDB2, AC117509.1, ABHD10, TAGLN3, RFKP2, TMPRSS7, C3orf52, MIR567, GCSAM, TBILA, SLC9C1, AC128688.1.
- chr3:171,600,404–171,810,950, 1 gene, copy number 9: PLD1.
- chr3:190,120,964–190,167,651, 3 genes, copy number 9 (within-gene range 8–9): P3H2-AS1, RNU6-1109P, NMNAT1P3.
- chr9:12,134–89,850, 7 genes, copy number 9: DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1.
- chr20:20,017,310–33,854,366, 274 genes, copy number 11 (broad region; genes not listed).
- chr20:33,993,646–64,327,972, 752 genes, copy number 11 (within-gene range 6–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
